Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EK-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site Code: Liver C22.0

Patient Key:
Surgical date:

1/19/11
ms

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 B12 B13 B14 B15
C1 C2 C3 C4 C5 C6 C7 C8
Liver mass segment 6 (1930.0 grams, 14.5 x 13.0 x 12.0 cm),
liver segment 7 mass (164.0 grams), hepatic nodule (0.4 x 0.3 x
0.1 cm).

DIAGNOSIS:

Liver, mass, segment VI resection: Moderately differentiated
hepatocellular carcinoma, forming a variegated mass with focal
necrosis measuring 14.5 x 13.0 x 12.0 cm. The tumor is partially
encapsulated with pushing border, and it shows no large vessel
invasion. The margins of resection are negative for neoplasm
(closest tumor free margin, 0.7 cm). The morphological findings
in the adjacent non-neoplastic liver parenchyma will be reported
as an addendum.

Immunoperoxidase stains show the tumor cells to be positive for
polyclonal CEA and Hep-1, and negative for AFP and cytokeratin
7. These findings support the above diagnosis.

Liver, mass, segment VII resection: Hepatocellular carcinoma
forming a solid nodule (1.3 x 1.0 x 0.9 cm), located 0.2 cm
from the surgical margin of resection. A separate nodule,
representing a cavernous hemangioma (1.2 x 1.0 x 0.5 cm) is also
identified.

Liver, nodule, excision: Sclerosing hemangioma.

Case seen in consultation with

ADDENDUM: Permanent sections of the non-neoplastic liver
demonstrate a mild simple steatosis with approximately 10-15%
macrovesicular steatosis of the lobular parenchyma. The
steatosis present in a non-zonal distribution, overall. The
portal areas present show no significant involvement by an
inflammatory cell infiltrate. The interlobular bile ducts are
intact and show no significant cellular injury. No significant
ductular proliferation is identified. The hepatic lobular
parenchyma is remarkable for a mild degree of macrovesicular
steatosis. Ballooning degeneration is not identified. Distinct
Mallory's hyaline formation is not identified. Apoptotic
hepatocytes are generally inconspicuous. Scattered irregular
apparently random clusters of neutrophils are present within the

[page 2 of 4]
lobular parenchyma and are most consistent with "surgical hepatitis". The iron stain demonstrates no significant iron accumulation within hepatocytes or Kupffer cells. The PAS stain after diastase digestion demonstrates no significant cytoplasmic globular inclusions within hepatocytes. The reticulin stain demonstrates intact trabecular architecture without areas of parenchymal collapse or abnormal plate growth. The trichrome stain highlights the portal areas and demonstrates no significant portal tract expansion by fibrosis and specifically periportal, bridging, and pericellular fibrosis are not identified.

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver, mass, segment VI resection: Hepatocellular carcinoma.
Hold to confirm with immunohistochemical stains.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): _____
☒ Multiple (specify location): Seg VI VII

Tumor Size

Greatest dimension: 14.6 cm

*Additional dimensions: 12.8 x 12.2 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC**Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☒ GII: Moderately differentiated
☐ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☐ pT1: Solitary tumor with no vascular invasion
☒ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined:

Number involved:

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known:

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 7.0 mm (seg VI), 2.0 mm (seg VII)

Specify margin:

- ☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma

* ☐ Carcinoma in situ absent

* ☐ Carcinoma in situ present

- ☐ Involved by invasive carcinoma

Other Margin

Specify margin:

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
* ☐ Present
* ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload

* ☐ Hepatitis (specify type):

* ☒ Other (specify): carcinous hemangioma (seg VI)
mild steatosis

Source: NCI Genomic Data Commons file 571121ee-4f88-4c56-8848-ba3335aeb886 (TCGA-DD-A1EK.AE199A35-2585-4363-8896-9B55B12C1BDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).